Gene-level copy-number profile of tumor specimen TCGA-ER-A42H-01A from TCGA case TCGA-ER-A42H, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.3 years (28,224 days).
Specimen TCGA-ER-A42H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.a336ae82-015e-4e75-ae8a-30eef59fc178.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A42H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e64e88d6-dbb8-4bb0-8daf-3d2e85e12f5b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 6,752; copy number 3: 10,186; copy number 4: 24,834; copy number 5: 7,374; copy number 6: 2,798; copy number 7: 4,316; copy number 8: 1,272; copy number 9: 1,111; copy number 11: 1,071; copy number 20: 31; copy number 22: 14; copy number 27: 48.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A42H-01A-11D-A24Q-01): tumor purity 0.94, ploidy 4.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,275 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:102,763,322–103,719,871, 14 genes, copy number 22: AC099567.1, COL11A1, SOD2P1, AC095032.2, AC095032.1, RN7SKP285, RNPC3, AMY2B, ACTG1P4, AMY2A, AMY1A, AC105272.1, AMY1B, AMYP1.
- chr1:118,712,999–121,580,524, 79 genes, copy number 20–27 (broad region; genes not listed).
- chr1:148,458,643–149,048,286, 15 genes, copy number 11 (within-gene range 6–11): AC245100.8, AC245100.7, PPIAL4G, RNVU1-27, NBPF14, NOTCH2NLB, RNU6-1171P, NUDT4B, SEC22B3P, AC245389.1, PDE4DIP, RN7SKP88, RNU2-38P, AC239802.1, AC239802.2.
- chr7:70,972–83,162,930, 1,532 genes, copy number 9–11 (within-gene range 2–11) (broad region; genes not listed).
- chr7:86,216,785–108,456,717, 480 genes, copy number 9 (broad region; genes not listed).
- chr7:150,824,627–159,233,377, 155 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
